Somatic mutation profile of tumor specimen C3N-01337-04 (aliquot CPT0087990009) from CPTAC case C3N-01337, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 52.9 years (19,312 days).
Specimen C3N-01337-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e053b88-95e6-42f8-922d-2013009f0f22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01337-31 (Blood Derived Normal), aliquot CPT0088050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4eda8307-4998-4092-b4db-b2d9d7e775ac

The open-access MAF lists 158 somatic variants for this specimen: 113 protein-altering or splice-affecting, 26 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 26, Intron 12, Nonsense Mutation 8, 5'UTR 3, Frame Shift Ins 3, 5'Flank 2, Frame Shift Del 2, Splice Region 2, Nonstop Mutation 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 107/358 reads (30%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG1 | c.531C>A p.C177* | Nonsense Mutation (SNP) | VAF 59/341 reads (17%) | catalogued as rs774109607; called by muse, mutect2, varscan2
- ARHGAP39 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.51); catalogued as rs758673314; called by muse, mutect2, varscan2
- ATP2A2 | c.2059G>C p.V687L | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV57875852; called by muse, mutect2, varscan2
- BOD1L2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1411926917; called by muse, mutect2, varscan2
- DISC1 | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.529); catalogued as COSV100790641; called by muse, mutect2, varscan2
- EIF2AK1 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as rs780373174; called by muse, mutect2, varscan2
- FOXN4 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1281290102; called by muse, mutect2, varscan2
- FREM1 | c.3540G>T p.Q1180H | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV66531396; called by muse, mutect2, varscan2
- GLIS1 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 27/170 reads (16%) | catalogued as COSV56553842; called by muse, mutect2, varscan2
- HGS | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1170120387; called by muse, mutect2, varscan2
- IGHG3 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 77/483 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); catalogued as rs371848750; called by muse, mutect2, varscan2
- ISLR2 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV100679759; called by muse, mutect2, varscan2
- KDM6A | c.3397C>T p.Q1133* | Nonsense Mutation (SNP) | VAF 80/258 reads (31%) | catalogued as COSV65036907; called by muse, mutect2, varscan2
- KIF21B | c.3913G>A p.E1305K (on ENST00000422435 / NM_001252100.2; = p.E1292K on NM_017596.4) | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760306875, COSV59761008; called by muse, mutect2, varscan2
- MICAL3 | c.4634C>T p.T1545M | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs183882165, COSV71588776; called by muse, mutect2, varscan2
- MPI | c.845-6C>T | Splice Region (SNP) | VAF 53/525 reads (10%) | catalogued as rs545077578; called by muse, mutect2
- MTMR6 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1328876968, COSV67809010; called by muse, mutect2, varscan2
- NBPF1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 56/511 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as rs753897903; called by muse, mutect2
- NFYC | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV58129267; called by muse, mutect2, varscan2
- OR4C12 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.77); catalogued as rs377698711, COSV58859595; called by muse, mutect2, varscan2
- OR51C1P | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs1378390661; called by muse, mutect2, varscan2
- PDZRN4 | c.2653C>A p.P885T (on ENST00000402685 / NM_001164595.2; = p.P627T on NM_013377.4) | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1172302262, COSV100114993; called by muse, mutect2, varscan2
- PKD2L2 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs773524035; called by muse, mutect2, varscan2
- PRKD1 | c.1555G>T p.V519F | Missense Mutation (SNP) | VAF 65/481 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV100121985, COSV59565714; called by muse, mutect2, varscan2
- RALGAPA2 | c.3743C>T p.S1248L | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1395002285; called by muse, mutect2, varscan2
- RICTOR | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1205555082, COSV99704799; called by muse, mutect2, varscan2
- RNASEL | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 87/519 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs1255186873; called by muse, mutect2, varscan2
- RNF152 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 43/279 reads (15%) | catalogued as COSV57183838; called by muse, mutect2, varscan2
- RPAP3 | c.1562C>G p.S521C | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs1188779531, COSV50042194; called by muse, mutect2, varscan2
- RPL26L1 | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1254580549; called by muse, mutect2, varscan2
- SEC31A | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV58875954; called by muse, mutect2, varscan2
- SLC5A4 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs759749538, COSV56673969; called by muse, mutect2, varscan2
- TCTE1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs541739413; called by muse, mutect2, varscan2
- TGFBR2 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 38/213 reads (18%) | catalogued as COSV99847240; called by muse, mutect2, varscan2
- TRUB2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as rs1400164292; called by muse, mutect2, varscan2
- WNT7A | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV53198092; called by muse, mutect2, varscan2
- ZNF415 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54704912, COSV99701481; called by muse, mutect2, varscan2
- ZNF451 | c.321T>G p.I107M | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs1031863814; called by muse, mutect2, varscan2
- ZNF677 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1222238638; called by muse, mutect2, varscan2
- ZNF777 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs779062163; called by muse, mutect2, varscan2
- ACBD6 | c.664del p.D222Tfs*20 | Frame Shift Del (DEL) | VAF 27/238 reads (11%) | called by mutect2, pindel, varscan2
- AGFG1 | c.1408A>G p.M470V | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKIRIN2 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANKS1B | c.775G>C p.G259R | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP3D1 | c.2139G>C p.L713F | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL15 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 131/453 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATAD2 | c.4080C>G p.S1360R | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- BZW1 | c.1000C>G p.Q334E | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CACNA2D1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCM2L | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.382); called by muse, mutect2
- CDKN2A | c.176_183del p.V59Afs*58 | Frame Shift Del (DEL) | VAF 41/288 reads (14%) | called by mutect2, pindel, varscan2
- CNOT3 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CTNNA2 | c.2555G>A p.G852E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCAF1 | c.3194G>T p.G1065V | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DENND1B | c.2164C>T p.H722Y | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DNAJC2 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- DSTYK | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP8 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHB1 | c.1930A>G p.R644G | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- FAAP100 | c.2380C>G p.L794V | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT1 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 43/184 reads (23%) | called by muse, mutect2, varscan2
- FES | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FHL3 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FILIP1L | c.2172G>C p.E724D (on ENST00000354552 / NM_182909.3; = p.E484D on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- FKBP10 | c.1460A>G p.D487G | Missense Mutation (SNP) | VAF 54/309 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FNBP1L | c.1817G>C p.*606Sext*11 (on ENST00000271234 / NM_001164473.2; = p.*548Sext*11 on NM_017737.5) | Nonstop Mutation (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- GABPA | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK3 | c.1454T>A p.L485Q | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HPN | c.413+3_413+27del | Splice Region (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel
- KIAA1522 | c.647T>A p.L216Q (on ENST00000373480 / NM_001198972.2; = p.L275Q on NM_020888.3) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- KIRREL2 | c.1541G>C p.G514A | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KRT6C | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LBR | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- MEI1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 63/255 reads (25%) | called by muse, mutect2, varscan2
- MINDY4 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MXRA5 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MYH8 | c.3813dup p.L1272Afs*4 | Frame Shift Ins (INS) | VAF 132/662 reads (20%) | called by mutect2, pindel, varscan2
- NAV1 | c.3390G>C p.E1130D | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NEK11 | c.1044G>C p.R348S | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NOTCH1 | c.2072dup p.T692Hfs*25 | Frame Shift Ins (INS) | VAF 298/756 reads (39%) | called by mutect2, pindel, varscan2
- OR52E4 | c.605T>C p.L202P | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAPPA2 | c.1669G>C p.A557P | Missense Mutation (SNP) | VAF 54/330 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PAPSS2 | c.35A>G p.Q12R | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, varscan2
- PDE7B | c.712-1G>C p.X238_splice | Splice Site (SNP) | VAF 39/230 reads (17%) | called by muse, mutect2, varscan2
- PHIP | c.3085G>C p.D1029H | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PLCD3 | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 118/397 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PLLP | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- RADIL | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- RNF175 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- RXFP1 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- SECISBP2 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 202/623 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SNX6 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT16H | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TADA2B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TEKT3 | c.467G>T p.W156L | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM123 | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 183/608 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM262 | c.33C>G p.F11L (on ENST00000530719 / NM_001282448.1; = p.F9L on NM_001242631.2) | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- TMEM74 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- TMPO | c.1673dup p.E559* | Frame Shift Ins (INS) | VAF 22/182 reads (12%) | called by mutect2, pindel
- TPX2 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- UBR4 | c.2087A>G p.D696G | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- UTP20 | c.1663A>T p.S555C | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- WNT9B | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2
- XDH | c.2182G>C p.D728H | Missense Mutation (SNP) | VAF 88/589 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- XRN1 | c.3971C>G p.S1324C | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- YEATS2 | c.1585C>G p.Q529E | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- YTHDF2 | c.1342T>C p.S448P | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZFAT | c.1934A>T p.Q645L | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- ZNF180 | c.1909C>A p.Q637K | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF229 | c.1261C>G p.Q421E | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF407 | c.1571C>G p.S524C | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF443 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- AC004593.2 | c.831C>G p.L277= | Silent (SNP) | VAF 70/410 reads (17%) | called by muse, mutect2, varscan2
- ADGRV1 | c.13524T>A p.A4508= | Silent (SNP) | VAF 40/281 reads (14%) | called by muse, mutect2, varscan2
- AGMAT | c.912C>T p.I304= | Silent (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- AP3D1 | c.2442G>A p.E814= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV61432039; called by muse, mutect2, varscan2
- CCDC86 | c.708G>A p.P236= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs752289054, COSV57124655, COSV99920261; called by mutect2, varscan2
- CEP250 | c.3390G>A p.A1130= | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as rs79678946, COSV61175086; called by muse, mutect2, varscan2
- CFAP69 | c.1920C>T p.P640= | Silent (SNP) | VAF 38/299 reads (13%) | catalogued as COSV100290362; called by muse, varscan2
- CFAP70 | c.126G>T p.L42= | Silent (SNP) | VAF 30/346 reads (9%) | called by muse, mutect2
- CLCN6 | c.2559C>G p.L853= | Silent (SNP) | VAF 53/357 reads (15%) | catalogued as COSV56741706, COSV56741794; called by muse, mutect2, varscan2
- DOCK5 | c.220C>T p.L74= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- DOCK5 | c.4641C>G p.L1547= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as rs143415337; called by muse, mutect2, varscan2
- DYNC1I1 | c.1755T>C p.R585= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as rs745738831; called by muse, mutect2, varscan2
- GNB5 | c.828C>T p.A276= (on ENST00000261837 / NM_016194.4; = p.A234= on NM_006578.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/234 reads (11%) | called by muse, mutect2, varscan2
- IFIH1 | c.2061G>A p.L687= | Silent (SNP) | VAF 25/141 reads (18%) | called by muse, varscan2
- KCNV2 | c.1128G>A p.L376= | Silent (SNP) | VAF 86/852 reads (10%) | catalogued as rs780625453, COSV66056341; called by muse, mutect2
- LEKR1 | c.750A>G p.L250= | Silent (SNP) | VAF 39/207 reads (19%) | catalogued as rs1233785291; called by muse, mutect2, varscan2
- LIG3 | c.1881G>C p.R627= | Silent (SNP) | VAF 31/211 reads (15%) | called by muse, mutect2, varscan2
- MAST4 | c.2868A>G p.L956= (on ENST00000403625 / NM_001164664.2; = p.L767= on NM_015183.3) | Silent (SNP) | VAF 68/221 reads (31%) | catalogued as rs755583713; called by muse, mutect2, varscan2
- PCDH1 | c.1689G>A p.E563= | Silent (SNP) | VAF 49/283 reads (17%) | catalogued as rs1364780623; called by muse, mutect2, varscan2
- SFT2D3 | c.195G>A p.L65= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs1236265396; called by muse, mutect2, varscan2
- TEX33 | c.363C>T p.D121= (on ENST00000381821 / NM_001163857.2; = p.D36= on NM_178552.4) | Silent (SNP) | VAF 33/255 reads (13%) | catalogued as rs755892652; called by muse, mutect2, varscan2
- TNS4 | c.156C>G p.A52= | Silent (SNP) | VAF 8/143 reads (6%) | catalogued as COSV54189078; called by muse, mutect2
- TRIM58 | c.378G>T p.T126= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1297312562; called by muse, mutect2, varscan2
- VIRMA | c.1383A>G p.K461= | Silent (SNP) | VAF 33/298 reads (11%) | called by muse, mutect2, varscan2
- VSIG8 | c.1137C>G p.A379= | Silent (SNP) | VAF 14/119 reads (12%) | called by mutect2, varscan2
- ZNF420 | c.1878G>A p.Q626= | Silent (SNP) | VAF 50/294 reads (17%) | catalogued as COSV100421416; called by muse, mutect2, varscan2
- AC011840.1 | n.1040G>A | RNA (SNP) | VAF 25/176 reads (14%) | called by muse, mutect2, varscan2
- AGR2 | c.140-43G>C | Intron (SNP) | VAF 27/181 reads (15%) | called by muse, mutect2, varscan2
- AP3D1 | c.2602-1052G>A | Intron (SNP) | VAF 21/99 reads (21%) | catalogued as rs775666312, COSV61430580; called by muse, mutect2, varscan2
- ASH1L | chr1:155563152 G>A | 5'Flank (SNP) | VAF 59/423 reads (14%) | called by muse, mutect2, varscan2
- ATL3 | chr11:63671617 G>C | 5'Flank (SNP) | VAF 11/30 reads (37%) | catalogued as COSV60297625; called by muse, mutect2, varscan2
- CA5B | c.143-1693dup | Intron (INS) | VAF 19/109 reads (17%) | called by mutect2, pindel, varscan2
- CTNND1 | c.2808+82del | Intron (DEL) | VAF 38/302 reads (13%) | called by mutect2, pindel, varscan2
- DLG2 | c.1978+3487C>G | Intron (SNP) | VAF 34/250 reads (14%) | called by muse, mutect2, varscan2
- DUSP3 | c.-1C>T | 5'UTR (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2
- FZD4 | c.286-32T>C | Intron (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- IFT57 | c.212+84G>C | Intron (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2
- IGHV3-38 | c.-1C>T | 5'UTR (SNP) | VAF 44/322 reads (14%) | called by muse, mutect2, varscan2
- MT1E | c.94+58C>G | Intron (SNP) | VAF 81/371 reads (22%) | called by muse, mutect2, varscan2
- NFKBIA | c.547+23C>T | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- NLE1 | c.18+68G>C | Intron (SNP) | VAF 29/218 reads (13%) | called by muse, mutect2, varscan2
- PCYT1A | c.335-141C>T | Intron (SNP) | VAF 42/274 reads (15%) | called by muse, mutect2, varscan2
- RAB35 | c.*70G>A | 3'UTR (SNP) | VAF 43/271 reads (16%) | catalogued as rs756879761, COSV57493045; called by muse, mutect2, varscan2
- SNX19 | c.2443+118G>A | Intron (SNP) | VAF 50/319 reads (16%) | catalogued as rs1400346432; called by muse, mutect2, varscan2
- TIGIT | c.-8del | 5'UTR (DEL) | VAF 38/279 reads (14%) | called by mutect2, pindel, varscan2
